Somatic mutation profile of tumor specimen MMRF_2344_2_BM_CD138pos (aliquot MMRF_2344_2_BM_CD138pos_T1_KHS5U_L13759) from MMRF case MMRF_2344, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,384 days).
Specimen MMRF_2344_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a531039-a46d-46fa-b67f-2691773e53cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2344_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2344_1_PB_Whole_C2_KHS5U_K15208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dee9712-133e-4d39-8ea5-73b217206315

The open-access MAF lists 99 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Intron 17, Silent 17, 3'UTR 9, Frame Shift Del 5, 5'UTR 4, RNA 3, Splice Site 3, Nonsense Mutation 3, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAP2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs759083931, COSV57734949; called by muse, mutect2, varscan2
- H1-4 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs777376445, COSV56801032; called by muse, mutect2, varscan2
- IGHJ4 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 46/52 reads (88%) | PolyPhen possibly damaging (0.54); catalogued as rs183645858; called by muse, varscan2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV3-53 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 198/794 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as rs782244844; called by muse, varscan2
- IGLV3-1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 80/146 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs373605544; called by muse, varscan2
- KCNJ12 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs143946927, COSV59164722; called by muse, varscan2
- KIF19 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs534125965; called by muse, mutect2, varscan2
- KLHL4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 103/104 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1400885102; called by muse, mutect2, varscan2
- PCM1 | c.436A>T p.M146L | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as COSV61515147; called by muse, mutect2, varscan2
- PKD2 | c.2596A>G p.K866E | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1480227336; called by muse, mutect2, varscan2
- PNPLA8 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.983); catalogued as rs201353226; called by muse, mutect2
- PPEF2 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs763143738, COSV54423837; called by muse, mutect2, varscan2
- PRR14L | c.4964G>A p.R1655K | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs758451724, COSV57884230; called by muse, mutect2
- PTPRT | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 81/293 reads (28%) | catalogued as COSV61977510; called by muse, mutect2, varscan2
- SALL3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1384399552; called by muse, mutect2, varscan2
- SPRR1A | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 152/667 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs151244576, COSV61081100; called by muse, mutect2, varscan2
- TOP2B | c.19T>C p.C7R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1235525179; called by muse, mutect2, varscan2
- ZFHX4 | c.4294C>T p.R1432C | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761737101, COSV50854696; called by muse, mutect2, varscan2
- ZGRF1 | c.5585G>A p.R1862Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1472187828; called by muse, mutect2, varscan2
- ACD | c.832T>C p.C278R (on ENST00000620338; = p.C189R on NM_022914.3) | Missense Mutation (SNP) | VAF 78/82 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRE2 | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- BST2 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC141 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CUL5 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYLD | c.1125G>A p.W375* | Nonsense Mutation (SNP) | VAF 17/19 reads (89%) | called by muse, mutect2, varscan2
- DSCAML1 | c.1118-1G>A p.X373_splice (on ENST00000321322; = p.X313_splice on NM_020693.4) | Splice Site (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- GPR149 | c.1413_1415del p.N471del | In Frame Del (DEL) | VAF 63/155 reads (41%) | called by pindel, varscan2
- HEPACAM | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ID4 | c.396_414del p.A133Rfs*13 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- IGHV2-70 | c.152_157delinsATAATT p.S51_M53delinsNNL | Missense Mutation (ONP) | VAF 31/33 reads (94%) | called by pindel, varscan2*
- IGHV2-70D | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 54/118 reads (46%) | called by muse, varscan2
- IGHV2-70D | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- IRAK2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LCT | c.4473_4474del p.Y1492Pfs*17 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- LMTK2 | c.4072T>A p.F1358I | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRBA | c.1301del p.S434Yfs*22 | Frame Shift Del (DEL) | VAF 86/192 reads (45%) | called by mutect2, pindel, varscan2
- MMP27 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MON2 | c.62del p.L21Cfs*23 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | called by mutect2, pindel, varscan2
- NLRP5 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 319/537 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEPK | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TMC1 | c.362+2T>A p.X121_splice | Splice Site (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- TTC3 | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZBED5 | c.1688A>T p.Y563F | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF292 | c.6206_6216delinsG p.T2069Rfs*60 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by pindel, varscan2*
- ZNF430 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 59/258 reads (23%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD61 | c.462G>A p.A154= | Silent (SNP) | VAF 36/249 reads (14%) | catalogued as rs1005269429; called by muse, mutect2, varscan2
- ASCC3 | c.147G>A p.K49= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100225273, COSV61226211; called by muse, mutect2, varscan2
- ATP6V1C2 | c.87C>T p.S29= | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as COSV55359371; called by muse, mutect2, varscan2
- DSE | c.540G>A p.V180= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100528237; called by muse, mutect2, varscan2
- FHDC1 | c.3177C>A p.G1059= | Silent (SNP) | VAF 76/180 reads (42%) | called by muse, mutect2, varscan2
- LYL1 | c.330C>T p.L110= | Silent (SNP) | VAF 34/51 reads (67%) | called by muse, mutect2, varscan2
- NHS | c.336G>A p.A112= | Silent (SNP) | VAF 19/20 reads (95%) | called by muse, mutect2, varscan2
- NYAP2 | c.1251G>A p.P417= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as rs371641080, COSV56012996; called by muse, mutect2, varscan2
- RASL11B | c.72C>T p.C24= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as rs1317861888; called by muse, mutect2, varscan2
- SLC19A1 | c.996G>A p.A332= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs757260467, COSV100229137; called by muse, mutect2, varscan2
- SLC7A9 | c.1167G>A p.T389= | Silent (SNP) | VAF 70/222 reads (32%) | catalogued as rs368549032, COSV99195201; called by muse, mutect2, varscan2
- SLIT3 | c.2985C>A p.I995= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- TAAR5 | c.267C>T p.P89= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as rs780841254; called by muse, mutect2, varscan2
- TNXB | c.894C>T p.N298= | Silent (SNP) | VAF 95/204 reads (47%) | called by muse, mutect2, varscan2
- WDR26 | c.48C>T p.S16= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1017677401; called by muse, mutect2
- XKR7 | c.867C>T p.D289= | Silent (SNP) | VAF 94/163 reads (58%) | catalogued as rs1303010032, COSV73813317; called by muse, mutect2, varscan2
- ZNF205 | c.1653C>T p.P551= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as rs904817224; called by muse, mutect2, varscan2
- AC110373.1 | n.448C>T | RNA (SNP) | VAF 16/124 reads (13%) | catalogued as rs1417516665; called by muse, mutect2, varscan2
- ARRB1 | c.1022+139C>A | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- B4GALT1 | c.*2129T>C | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- CAMK1D | c.300-35595T>A | Intron (SNP) | VAF 46/76 reads (61%) | called by muse, mutect2, varscan2
- CDV3 | c.*859C>T | 3'UTR (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- CELF2 | c.1076-2192G>A | Intron (SNP) | VAF 94/200 reads (47%) | catalogued as rs770830439; called by muse, mutect2, varscan2
- CFAP65 | c.2211+670C>A | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- CLEC16A | c.2641+212T>C | Intron (SNP) | VAF 129/266 reads (48%) | called by muse, mutect2, varscan2
- CNGA2 | c.*263A>G | 3'UTR (SNP) | VAF 59/60 reads (98%) | called by muse, mutect2, varscan2
- CRCP | c.*789G>T | 3'UTR (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- DNAJC14 | chr12:55832172 T>G | 5'Flank (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- DOCK7 | c.1801-1195G>A | Intron (SNP) | VAF 58/134 reads (43%) | called by muse, mutect2, varscan2
- ETNK1 | c.416+397T>A | Intron (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2
- GVINP1 | n.2996C>A | RNA (SNP) | VAF 113/280 reads (40%) | called by muse, mutect2, varscan2
- HSPA8 | c.1120+76A>G | Intron (SNP) | VAF 213/429 reads (50%) | catalogued as rs1181548858; called by muse, mutect2, varscan2
- HTT | c.*2117A>C | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- IFT122 | c.-40G>T | 5'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- IFT122 | c.-39A>T | 5'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- IRF5 | c.*754G>A | 3'UTR (SNP) | VAF 41/71 reads (58%) | called by muse, mutect2, varscan2
- KRAS | c.112-7078C>A | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- LTB | c.209-46T>A | Intron (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2
- MMP25 | c.99+9G>T | Intron (SNP) | VAF 20/38 reads (53%) | catalogued as rs1281056323; called by muse, mutect2, varscan2
- NR1I3 | c.-106G>A | 5'UTR (SNP) | VAF 115/409 reads (28%) | catalogued as rs568943207, COSV63468785; called by muse, mutect2, varscan2
- NSD2 | c.2986-76G>A | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- PDE1C | c.1892-8884del | Intron (DEL) | VAF 29/55 reads (53%) | catalogued as rs879474817; called by mutect2, varscan2
- PPP2CA | c.*121A>T | 3'UTR (SNP) | VAF 48/141 reads (34%) | catalogued as rs1423096456; called by muse, mutect2, varscan2
- PTPRF | c.*307G>A | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.2428C>T | RNA (SNP) | VAF 137/457 reads (30%) | called by muse, mutect2, varscan2
- RNF43 | c.2308+208T>C | Intron (SNP) | VAF 42/72 reads (58%) | catalogued as rs1271568451; called by muse, mutect2, varscan2
- RORA | c.196+51361C>T | Intron (SNP) | VAF 142/226 reads (63%) | catalogued as rs372625965, COSV55045516; called by muse, mutect2, varscan2
- S1PR3 | c.-194G>A | 5'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TPK1 | c.*31T>C | 3'UTR (SNP) | VAF 54/383 reads (14%) | called by muse, mutect2, varscan2
- TRAPPC4 | c.176-80dup | Intron (INS) | VAF 42/128 reads (33%) | called by pindel, varscan2
- WHRN | c.1167-295T>C | Intron (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- XKR8 | chr1:27959638 T>A | 5'Flank (SNP) | VAF 84/173 reads (49%) | called by muse, mutect2, varscan2
